Somatic mutation profile of tumor specimen TCGA-91-8499-01A (aliquot TCGA-91-8499-01A-11D-2393-08) from TCGA case TCGA-91-8499, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 76.3 years (27,853 days).
Specimen TCGA-91-8499-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b04d9eb-98b0-4aff-8168-53a6b31bd9c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-8499-10A (Blood Derived Normal), aliquot TCGA-91-8499-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0aef9a8-1d05-40c0-8225-e8ea61e5f8d3

The open-access MAF lists 347 somatic variants for this specimen: 271 protein-altering or splice-affecting, 71 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 224, Silent 71, Nonsense Mutation 23, Frame Shift Del 8, Frame Shift Ins 5, Splice Site 4, Splice Region 3, In Frame Del 2, Intron 2, Translation Start Site 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 83/101 reads (82%) | catalogued as rs786202918, CM981673, COSV100910801, COSV64288504; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.712_729del p.C238_M243del | In Frame Del (DEL) | VAF 33/56 reads (59%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCB7 | c.1128G>T p.M376I (on ENST00000373394 / NM_001271696.3; = p.M377I on NM_004299.6) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV99504363; called by muse, mutect2, varscan2
- ACSM2B | c.1482C>G p.I494M | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV100312295, COSV100312672; called by muse, mutect2, varscan2
- ACSM2B | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100312673; called by muse, mutect2, varscan2
- ACTL8 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 84/115 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as COSV100958625; called by muse, mutect2, varscan2
- ADAM2 | c.1310T>C p.L437P | Missense Mutation (SNP) | VAF 462/544 reads (85%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as rs745560777, COSV99697327; called by muse, mutect2, varscan2
- ADAM21 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.162); catalogued as COSV99961014; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3451G>T p.G1151W | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.663); catalogued as COSV101001818; called by muse, mutect2, varscan2
- ADCY8 | c.3011G>A p.G1004E | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV53905875; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.725T>G p.F242C | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100416486; called by muse, mutect2, varscan2
- ADGRB1 | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.248); catalogued as COSV100029694; called by muse, mutect2, varscan2
- ADGRG4 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 167/219 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99795476; called by muse, mutect2, varscan2
- AHI1 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99662734; called by muse, mutect2, varscan2
- ALDH3A2 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 87/276 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs765401990, CM087212, COSV99449901; called by muse, mutect2, varscan2
- ALDH8A1 | c.754C>G p.L252V | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768610596, COSV55640464, COSV99664733, COSV99664862; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6917C>G p.S2306C | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99783346; called by muse, mutect2, varscan2
- ARF6 | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100028431; called by muse, mutect2, varscan2
- ART1 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.287); catalogued as rs767771808, COSV99167167; called by muse, mutect2, varscan2
- ATMIN | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100214628; called by muse, mutect2, varscan2
- ATP8A2 | c.1078G>T p.G360* | Nonsense Mutation (SNP) | VAF 77/122 reads (63%) | catalogued as COSV99681977; called by muse, varscan2
- ATP8A2 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 78/122 reads (64%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.881); catalogued as COSV99681979; called by muse, varscan2
- B3GAT2 | c.431C>A p.T144K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV100016968; called by muse, mutect2, varscan2
- BAIAP3 | c.3221C>T p.T1074M | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201353225, COSV99136218; called by muse, mutect2, varscan2
- BCHE | c.1383G>T p.W461C | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012532; called by muse, mutect2, varscan2
- BCL2L11 | c.575G>T p.R192L (on ENST00000393256 / NM_138621.5; = p.R132L on NM_006538.5) | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100427340; called by muse, mutect2, varscan2
- BPIFB6 | c.913T>A p.Y305N | Missense Mutation (SNP) | VAF 80/218 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100848515; called by muse, mutect2, varscan2
- BPTF | c.4207G>A p.G1403R | Missense Mutation (SNP) | VAF 108/179 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.231); catalogued as COSV100074971; called by muse, mutect2, varscan2
- BRCA1 | c.4946G>C p.R1649T | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs876660509, COSV100524165, COSV58790283, COSV58798820; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- BRINP3 | c.1913C>G p.P638R | Missense Mutation (SNP) | VAF 137/263 reads (52%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.827); catalogued as COSV100818760; called by muse, mutect2, varscan2
- BTNL2 | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100896087; called by muse, mutect2, varscan2
- C6orf118 | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV100024524, COSV57814139; called by muse, mutect2, varscan2
- CABS1 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.621); catalogued as COSV99909070; called by muse, mutect2, varscan2
- CALCR | c.108dup p.K37Qfs*21 | Frame Shift Ins (INS) | VAF 88/197 reads (45%) | catalogued as rs748018172; called by mutect2, pindel, varscan2
- CARD18 | c.207C>A p.C69* | Nonsense Mutation (SNP) | VAF 149/237 reads (63%) | catalogued as rs1267638929, COSV101596033; called by muse, mutect2, varscan2
- CARMIL3 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs1267555738, COSV100549596; called by muse, mutect2, varscan2
- CCDC82 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV99567312; called by muse, mutect2, varscan2
- CCDC93 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100098792; called by muse, mutect2, varscan2
- CD163 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 88/214 reads (41%) | catalogued as COSV100775837; called by muse, mutect2, varscan2
- CDH10 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.21); catalogued as COSV100051463, COSV52569250; called by muse, mutect2, varscan2
- CDH17 | c.1925T>A p.V642E | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.87); PolyPhen benign (0.186); catalogued as rs1392303843, COSV99217445; called by muse, mutect2, varscan2
- CDH8 | c.168G>C p.L56F | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.924); catalogued as COSV100181538, COSV54867130, COSV54868486; called by muse, mutect2, varscan2
- CEP170 | c.4687G>T p.D1563Y | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100317089; called by muse, mutect2, varscan2
- CHL1 | c.1259-1G>C p.X420_splice (on ENST00000397491 / NM_001253387.1; = p.X436_splice on NM_006614.4) | Splice Site (SNP) | VAF 71/137 reads (52%) | catalogued as COSV99851068, COSV99851208; called by muse, varscan2
- CHL1 | c.1399G>A p.E467K (on ENST00000397491 / NM_001253387.1; = p.E483K on NM_006614.4) | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as COSV99851210; called by muse, varscan2
- CHL1 | c.1459G>A p.E487K (on ENST00000397491 / NM_001253387.1; = p.E503K on NM_006614.4) | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.179); catalogued as COSV99851211; called by muse, varscan2
- CHL1 | c.1535G>C p.R512T (on ENST00000397491 / NM_001253387.1; = p.R528T on NM_006614.4) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV56586248, COSV99851213; called by muse, varscan2
- CHRDL1 | c.1114G>A p.V372I (on ENST00000372045; = p.V378I on NM_145234.4) | Missense Mutation (SNP) | VAF 86/107 reads (80%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.959); catalogued as rs747422590, COSV54323200; called by muse, mutect2, varscan2
- CNOT4 | c.2042C>T p.S681F (on ENST00000541284 / NM_001190850.1; = p.S607F on NM_013316.4) | Missense Mutation (SNP) | VAF 83/286 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); catalogued as rs760949147, COSV100835948; called by muse, mutect2, varscan2
- CNTNAP5 | c.3497C>A p.S1166Y | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101443560; called by muse, mutect2, varscan2
- COA8 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs747124583, CD149792; called by muse, mutect2, varscan2
- COL25A1 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.991); catalogued as COSV101211422; called by muse, mutect2, varscan2
- COL5A1 | c.2152G>C p.G718R | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100879949; called by muse, mutect2, varscan2
- COPS2 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100157247; called by muse, mutect2, varscan2
- CORIN | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs146275416; called by muse, mutect2
- CPA3 | c.154T>C p.W52R | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291454727, COSV99936157; called by muse, mutect2, varscan2
- CPB1 | c.767C>G p.A256G | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99294308; called by muse, mutect2, varscan2
- CPNE9 | c.905T>A p.V302E | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99808261; called by muse, mutect2, varscan2
- CSMD2 | c.3770G>C p.R1257P | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99589945; called by muse, mutect2, varscan2
- CSMD3 | c.6934C>T p.L2312F (on ENST00000297405 / NM_001363185.1; = p.L2208F on NM_052900.3) | Missense Mutation (SNP) | VAF 67/260 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as rs779974197, COSV99834425, COSV99839050; called by muse, mutect2, varscan2
- CTDP1 | c.1837A>T p.N613Y | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV99310603; called by muse, mutect2, varscan2
- CYP11B1 | c.1307G>T p.R436M | Missense Mutation (SNP) | VAF 139/247 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV99455122; called by muse, mutect2, varscan2
- CYP27B1 | c.95C>G p.S32* | Nonsense Mutation (SNP) | VAF 65/362 reads (18%) | catalogued as COSV99141568; called by muse, mutect2, varscan2
- DDO | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374639603, COSV100927848; called by muse, mutect2, varscan2
- DLG1 | c.1384A>G p.R462G | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV100015354; called by muse, mutect2, varscan2
- DNAH10 | c.7702G>T p.D2568Y (on ENST00000409039; = p.D2507Y on NM_207437.3) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs758837808, COSV101292255; called by muse, mutect2, varscan2
- DNAH5 | c.2848A>G p.M950V | Missense Mutation (SNP) | VAF 198/246 reads (80%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99449801; called by muse, mutect2, varscan2
- DNAJC13 | c.2550-1G>T p.X850_splice | Splice Site (SNP) | VAF 41/63 reads (65%) | catalogued as COSV99607278; called by muse, mutect2, varscan2
- DNM1L | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56774332, COSV99846075; called by muse, mutect2, varscan2
- DNMT3A | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1457666600, COSV99262335; called by muse, mutect2, varscan2
- DOP1A | c.1312G>C p.V438L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99381910; called by muse, mutect2, varscan2
- DPPA5 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV100951497; called by muse, mutect2, varscan2
- DSCAM | c.5216G>A p.G1739E | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101260155; called by muse, mutect2, varscan2
- EPB41L2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.146); catalogued as rs1331050549, COSV100440732; called by muse, mutect2, varscan2
- ERC2 | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs772063893, COSV55636646; called by muse, mutect2, varscan2
- EVI5 | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100789679; called by muse, mutect2, varscan2
- F9 | c.1028A>T p.N343I | Missense Mutation (SNP) | VAF 116/148 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99496580; called by muse, mutect2, varscan2
- FAM155A | c.323C>A p.A108E | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs1247820134, COSV101028001, COSV65556769; called by muse, varscan2
- FAM181A | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99967887; called by muse, mutect2, varscan2
- FBXO42 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 53/75 reads (71%) | SIFT tolerated (0.24); PolyPhen benign (0.285); catalogued as COSV100981769; called by muse, mutect2, varscan2
- FCRL2 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.261); catalogued as COSV100829914; called by muse, mutect2, varscan2
- FCRL2 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs375240841, COSV100829915; called by muse, mutect2, varscan2
- FCRLA | c.361C>A p.R121S (on ENST00000367959; = p.R98S on NM_032738.4) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as COSV99376017; called by muse, mutect2, varscan2
- FGF22 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs748495939, COSV51260908, COSV51261226; called by muse, mutect2, varscan2
- FGF9 | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 60/80 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as COSV101210967; called by muse, mutect2, varscan2
- FSTL5 | c.283C>A p.R95S | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV60233284; called by muse, mutect2, varscan2
- FUT9 | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100133421, COSV100133635; called by muse, mutect2, varscan2
- GALNT18 | c.1316A>C p.K439T | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV99924614; called by muse, mutect2, varscan2
- GDF6 | c.804G>C p.R268S | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.85); PolyPhen benign (0.012); catalogued as COSV54623054, COSV99748060; called by muse, mutect2, varscan2
- GFRAL | c.18C>G p.F6L | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100475158; called by muse, mutect2, varscan2
- GJC1 | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 96/178 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV100395177; called by muse, mutect2, varscan2
- GNAI3 | c.965A>T p.H322L | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100879880; called by muse, mutect2, varscan2
- GPHN | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs1173184667, COSV100016296; called by muse, mutect2, varscan2
- GRIA1 | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.897); catalogued as COSV99599830; called by muse, mutect2, varscan2
- GRM5 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV59591675, COSV59598882; called by muse, mutect2, varscan2
- HERC2 | c.3761G>T p.G1254V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99873796; called by muse, mutect2, varscan2
- HERC2 | c.3172C>T p.Q1058* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99873799, COSV99876418; called by muse, mutect2, varscan2
- HEXIM1 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as COSV100203481; called by muse, varscan2
- HS3ST5 | c.128T>A p.I43N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.261); catalogued as COSV100450908; called by muse, mutect2, varscan2
- HTR1A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 53/66 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV100109018; called by muse, mutect2, varscan2
- HTR2B | c.167G>A p.W56* | Nonsense Mutation (SNP) | VAF 42/139 reads (30%) | catalogued as COSV99295306; called by muse, mutect2, varscan2
- IGF2R | c.6352A>G p.S2118G | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100807375; called by muse, mutect2, varscan2
- IRAG2 | c.2942A>G p.Y981C (on ENST00000636465; = p.Y26C on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV100611797; called by muse, mutect2, varscan2
- IRS1 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs372100778, COSV100524511; called by muse, mutect2, varscan2
- JPH1 | c.1849C>G p.P617A | Missense Mutation (SNP) | VAF 232/424 reads (55%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as rs779379679, COSV100646605; called by muse, mutect2, varscan2
- KAT2B | c.1823A>G p.Y608C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755056109, COSV99769283; called by muse, mutect2, varscan2
- KCNH5 | c.855G>T p.R285S | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100526591, COSV59777439; called by muse, mutect2, varscan2
- KCNU1 | c.863T>A p.L288* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV101299080; called by muse, mutect2
- KDM6B | c.4771G>A p.E1591K | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs778857767, COSV99641417; called by muse, mutect2, varscan2
- KPNA1 | c.1079G>C p.W360S | Missense Mutation (SNP) | VAF 72/122 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100724215; called by muse, mutect2, varscan2
- KRTAP13-4 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 123/223 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as COSV100481744; called by muse, mutect2, varscan2
- KTN1 | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101255218; called by muse, mutect2, varscan2
- LAMB1 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99740410, COSV99740733; called by muse, mutect2, varscan2
- LIN37 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs772947202, COSV99040575, COSV99137443; called by muse, mutect2, varscan2
- LMBRD2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99682847; called by muse, mutect2, varscan2
- LRRC25 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 86/99 reads (87%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs34347418, COSV100170517; called by muse, mutect2, varscan2
- LRRC49 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV99537507; called by muse, mutect2, varscan2
- LRRC59 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 61/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs143077743; called by muse, mutect2, varscan2
- LRRIQ3 | c.1453C>A p.Q485K | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100598827; called by muse, mutect2, varscan2
- LRRTM4 | c.717C>A p.N239K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101297559; called by muse, mutect2, varscan2
- MAGEB2 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100975663, COSV66780301; called by mutect2, varscan2
- MALT1 | c.1740G>A p.W580* | Nonsense Mutation (SNP) | VAF 18/137 reads (13%) | catalogued as COSV100618704; called by muse, mutect2, varscan2
- MAP3K13 | c.1903A>C p.N635H | Missense Mutation (SNP) | VAF 151/704 reads (21%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV99407171; called by muse, mutect2, varscan2
- MC3R | c.909C>A p.S303R | Missense Mutation (SNP) | VAF 163/331 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54764005; called by muse, mutect2, varscan2
- MCCC2 | c.1453A>G p.I485V | Missense Mutation (SNP) | VAF 47/57 reads (82%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.029); catalogued as COSV100040166; called by muse, mutect2, varscan2
- MDK | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs1426678833, COSV100551419; called by muse, mutect2, varscan2
- MKRN1 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 85/165 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99751652; called by muse, mutect2, varscan2
- MORN1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100087874; called by muse, mutect2, varscan2
- MOSPD1 | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 80/106 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100887836; called by muse, mutect2, varscan2
- MUC17 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 114/407 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100073255; called by muse, mutect2, varscan2
- MUC5B | c.2904G>C p.E968D | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as COSV101500331; called by muse, mutect2, varscan2
- MYH6 | c.734T>C p.F245S | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs371608354; called by muse, mutect2, varscan2
- MYH7 | c.3802C>A p.R1268S | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100806113, COSV62519590; called by muse, mutect2, varscan2
- MYT1L | c.2681T>C p.L894P | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101220770; called by muse, mutect2, varscan2
- NAT8 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as COSV99722014; called by muse, mutect2, varscan2
- NCALD | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99637243; called by muse, mutect2, varscan2
- NCOR1 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 102/127 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1391053845, COSV51984854; called by muse, mutect2, varscan2
- NDRG3 | c.813C>T p.V271= (on ENST00000349004 / NM_032013.4; = p.V259= on NM_022477.4) | Splice Region (SNP) | VAF 20/117 reads (17%) | catalogued as rs777659603, COSV62421148; called by muse, mutect2, varscan2
- NEK1 | c.3016C>G p.Q1006E | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV101455686; called by muse, mutect2, varscan2
- NHEJ1 | c.472C>A p.H158N | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as COSV100592091; called by muse, mutect2, varscan2
- NIM1K | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 69/338 reads (20%) | catalogued as COSV100390162; called by muse, mutect2, varscan2
- NLGN3 | c.1493G>T p.G498V (on ENST00000358741 / NM_181303.2; = p.G478V on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100704765, COSV62443492; called by muse, mutect2, varscan2
- NMUR1 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV100531882, COSV100531973; called by muse, mutect2, varscan2
- NOS2 | c.2129G>T p.R710M | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100569665; called by muse, mutect2, varscan2
- NOTCH2 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 69/126 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs782038512, COSV99864105; called by muse, mutect2, varscan2
- NSD3 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 68/865 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1174961740, COSV100388657; called by muse, mutect2
- NTHL1 | c.498G>C p.Q166H (on ENST00000219066; = p.Q158H on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV99526319; called by muse, mutect2, varscan2
- OR10A5 | c.785G>A p.W262* | Nonsense Mutation (SNP) | VAF 112/229 reads (49%) | catalogued as COSV100203470; called by muse, mutect2, varscan2
- OR2M4 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100141232; called by muse, mutect2, varscan2
- OR4C12 | c.859C>A p.L287I | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as COSV100078490; called by muse, mutect2, varscan2
- OR4C15 | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.104); catalogued as COSV58950958; called by muse, mutect2, varscan2
- OR52B2 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101603945; called by muse, mutect2, varscan2
- OR5D16 | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV101003944; called by muse, mutect2, varscan2
- OR5K3 | c.717T>A p.C239* | Nonsense Mutation (SNP) | VAF 64/112 reads (57%) | catalogued as COSV101051644, COSV67350157; called by muse, mutect2, varscan2
- OR6T1 | c.575C>A p.T192N | Missense Mutation (SNP) | VAF 83/106 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1443625439, COSV100189973, COSV58305994; called by muse, mutect2, varscan2
- OR8H3 | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57908471; called by muse, mutect2
- OR9G1 | c.197C>A p.S66* | Nonsense Mutation (SNP) | VAF 42/156 reads (27%) | catalogued as rs746698658, COSV100380410; called by muse, mutect2, varscan2
- OR9G4 | c.104A>T p.Y35F | Missense Mutation (SNP) | VAF 64/101 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100265127, COSV57248769; called by muse, mutect2, varscan2
- PAPOLG | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99474726; called by muse, mutect2
- PBDC1 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100972826; called by muse, mutect2, varscan2
- PCDHGA7 | c.1442G>T p.S481I | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV99538391; called by muse, mutect2, varscan2
- PELI2 | c.1017G>T p.R339S | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV50714055; called by muse, mutect2, varscan2
- PEX5L | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.119); catalogued as COSV99828753; called by muse, mutect2, varscan2
- PGM5 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 56/72 reads (78%) | catalogued as COSV101123443; called by muse, mutect2, varscan2
- PKHD1L1 | c.11509C>A p.P3837T | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758332120, COSV101006143; called by muse, mutect2, varscan2
- PLA2G4A | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV100820541; called by muse, mutect2, varscan2
- PLD1 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); catalogued as rs200560558, COSV100578144; called by muse, mutect2, varscan2
- PLXNB1 | c.3129G>T p.W1043C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396943889, COSV99602837; called by muse, mutect2, varscan2
- POGLUT2 | c.1373A>G p.K458R | Missense Mutation (SNP) | VAF 45/54 reads (83%) | SIFT tolerated (0.62); PolyPhen benign (0.042); catalogued as COSV101050789; called by muse, mutect2, varscan2
- POM121L12 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 47/58 reads (81%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as COSV101374917; called by muse, mutect2, varscan2
- POU3F4 | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.325); catalogued as COSV100937252; called by muse, mutect2, varscan2
- PPM1H | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV57378395; called by muse, mutect2, varscan2
- PRKAA1 | c.736C>G p.Q246E | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.01); catalogued as COSV57185736; called by muse, mutect2, varscan2
- PRPF40A | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100582840; called by muse, mutect2, varscan2
- PRPF4B | c.2506G>T p.G836W | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100528202, COSV61784400; called by muse, mutect2, varscan2
- PSD3 | c.2209G>C p.E737Q (on ENST00000440756; = p.E736Q on NM_015310.4) | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.473); catalogued as COSV99675970; called by muse, mutect2, varscan2
- PTPN14 | c.1490C>G p.T497S | Missense Mutation (SNP) | VAF 260/326 reads (80%) | SIFT tolerated (0.75); PolyPhen benign (0.039); catalogued as COSV100872581; called by muse, mutect2, varscan2
- PTPN5 | c.1080G>T p.R360= | Splice Region (SNP) | VAF 23/105 reads (22%) | catalogued as COSV100659905; called by muse, mutect2, varscan2
- PTPRU | c.3851C>T p.S1284F | Missense Mutation (SNP) | VAF 49/73 reads (67%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); catalogued as COSV60526404; called by muse, mutect2, varscan2
- RAB28 | c.26A>T p.Q9L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1432867668, COSV99986243; called by muse, mutect2, varscan2
- RAB39B | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65624851; called by muse, mutect2, varscan2
- RBM46 | c.672G>C p.E224D | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV55981868, COSV99908103; called by muse, mutect2, varscan2
- RDH16 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 52/184 reads (28%) | catalogued as COSV100660114; called by muse, mutect2, varscan2
- RFX7 | c.1685G>A p.R562Q (on ENST00000559447 / NM_001368074.1; = p.R659Q on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1288018809, COSV100428798; called by muse, mutect2, varscan2
- RGS22 | c.1824-1G>T p.X608_splice | Splice Site (SNP) | VAF 43/70 reads (61%) | catalogued as COSV100693264; called by muse, mutect2, varscan2
- RHAG | c.1217C>G p.P406R | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs773994118, COSV100006603; called by muse, mutect2, varscan2
- RIF1 | c.6154G>A p.D2052N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.023); catalogued as COSV99690584; called by muse, mutect2, varscan2
- RP1L1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 63/96 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs374360526; called by muse, mutect2, varscan2
- RPL7L1 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100491698; called by muse, mutect2, varscan2
- SAMD3 | c.751C>G p.H251D | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100931773; called by muse, mutect2, varscan2
- SATB2 | c.479C>A p.S160* | Nonsense Mutation (SNP) | VAF 56/98 reads (57%) | catalogued as COSV99611306; called by muse, mutect2, varscan2
- SCN10A | c.5378T>G p.V1793G | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101479393; called by muse, mutect2, varscan2
- SCRIB | c.3506C>T p.T1169M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545423403, COSV100253297; called by muse, mutect2, varscan2
- SEL1L3 | c.2341G>T p.A781S | Missense Mutation (SNP) | VAF 67/82 reads (82%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as COSV99340304; called by muse, mutect2, varscan2
- SEMA6C | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 20/36 reads (56%) | catalogued as COSV100501310; called by muse, mutect2, varscan2
- SEMA6C | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV100501311; called by muse, mutect2, varscan2
- SERPINI1 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV99855075, COSV99855497; called by muse, mutect2, varscan2
- SETMAR | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as COSV100740869; called by muse, mutect2, varscan2
- SIGLEC10 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT tolerated (0.99); PolyPhen benign (0.103); catalogued as COSV100218981; called by muse, mutect2, varscan2
- SIX1 | c.442T>C p.Y148H | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99903350; called by muse, mutect2
- SLC17A1 | c.1308G>T p.M436I | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99765772; called by muse, mutect2, varscan2
- SLC1A6 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 63/82 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV99693757; called by muse, mutect2, varscan2
- SLC28A3 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs202155610, COSV100883142; called by muse, mutect2
- SLC2A10 | c.848C>G p.A283G | Missense Mutation (SNP) | VAF 104/254 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.492); catalogued as rs145994112, CM1210986, COSV100826370; called by muse, mutect2, varscan2
- SLC2A11 | c.1179C>G p.I393M (on ENST00000345044 / NM_001024938.4; = p.I400M on NM_030807.5) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as rs138949711; called by muse, mutect2
- SLC2A9 | c.761A>G p.D254G | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs1255751599, COSV53324233, COSV99304631; called by muse, mutect2, varscan2
- SLC6A5 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 82/150 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100116890; called by muse, mutect2, varscan2
- SLCO6A1 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs1188297782, COSV101134335; called by muse, varscan2
- SMPD3 | c.155C>A p.P52Q | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT deleterious (0.05); PolyPhen benign (0.438); catalogued as COSV99545666; called by muse, mutect2, varscan2
- SNTG1 | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99383691; called by muse, mutect2, varscan2
- SOX11 | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100431111; called by muse, mutect2, varscan2
- SRCIN1 | c.2744C>T p.A915V (on ENST00000621492; = p.A881V on NM_025248.3) | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1344055669; called by muse, mutect2, varscan2
- STAM2 | c.888G>C p.K296N | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99813070; called by muse, mutect2, varscan2
- STRN4 | c.537A>G p.R179= | Splice Region (SNP) | VAF 89/239 reads (37%) | catalogued as COSV99623632; called by muse, mutect2, varscan2
- TAAR9 | c.254T>A p.V85E | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101453343; called by muse, mutect2, varscan2
- TAF3 | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100720142; called by muse, mutect2
- TASP1 | c.553A>G p.N185D | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1022259313, COSV100534618; called by muse, mutect2, varscan2
- TBATA | c.544del p.A182Qfs*63 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs759960781; called by mutect2, pindel, varscan2
- TEKT4 | c.1001A>C p.K334T | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553396287, COSV99726388; called by muse, mutect2, varscan2
- TERF1 | c.928G>T p.G310C | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV99401207; called by muse, mutect2, varscan2
- TMEM126B | c.119G>T p.S40I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV100729020; called by muse, mutect2, varscan2
- TMEM241 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.55); PolyPhen benign (0.085); catalogued as COSV101271731; called by muse, mutect2, varscan2
- TNIP3 | c.530C>G p.S177C | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99284487; called by muse, mutect2, varscan2
- TRA2B | c.649C>A p.R217S | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52024826, COSV99373261; called by muse, mutect2, varscan2
- TRAIP | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100513210; called by muse, mutect2, varscan2
- TRAPPC13 | c.1219T>C p.C407R | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV99198889; called by muse, mutect2, varscan2
- TSBP1 | c.1584G>C p.K528N (on ENST00000617061; = p.K533N on NM_006781.5) | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100898801; called by muse, mutect2, varscan2
- TSC22D4 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs750757880, COSV100190272; called by muse, mutect2, varscan2
- TSPAN7 | c.271-1G>T p.X91_splice | Splice Site (SNP) | VAF 48/80 reads (60%) | catalogued as COSV99730729; called by muse, mutect2, varscan2
- TTN | c.85001C>G p.A28334G (on ENST00000591111; = p.A20910G on NM_003319.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | PolyPhen possibly damaging (0.716); catalogued as COSV100612786; called by muse, mutect2, varscan2
- TTN | c.85000G>A p.A28334T (on ENST00000591111; = p.A20910T on NM_003319.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | PolyPhen possibly damaging (0.73); catalogued as COSV100612789; called by muse, mutect2, varscan2
- TTN | c.67247C>A p.P22416Q (on ENST00000591111; = p.P14992Q on NM_003319.4) | Missense Mutation (SNP) | VAF 34/60 reads (57%) | PolyPhen probably damaging (0.999); catalogued as COSV100612797; called by muse, mutect2, varscan2
- TTYH1 | c.1243C>T p.R415* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as rs1569270364, COSV56613460; called by muse, mutect2, varscan2
- UBAP1 | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 143/172 reads (83%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.729); catalogued as COSV99902813; called by muse, mutect2, varscan2
- UNC13A | c.5092G>T p.G1698C | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV99408351; called by muse, varscan2
- VRTN | c.179C>A p.S60* | Nonsense Mutation (SNP) | VAF 100/184 reads (54%) | catalogued as COSV99832249; called by muse, mutect2, varscan2
- WDFY1 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99239454; called by muse, mutect2, varscan2
- WDR72 | c.1471G>T p.V491L | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100854457; called by muse, mutect2, varscan2
- ZBTB12 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 74/141 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV64993580; called by muse, mutect2, varscan2
- ZFHX4 | c.5845G>T p.G1949* | Nonsense Mutation (SNP) | VAF 17/142 reads (12%) | catalogued as COSV50807889; called by muse, mutect2, varscan2
- ZMAT4 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV52700011, COSV99909936; called by muse, mutect2, varscan2
- ZMYM3 | c.3808G>A p.G1270S | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.75); PolyPhen benign (0.024); catalogued as COSV100077884; called by muse, mutect2, varscan2
- ZNF217 | c.1727T>A p.L576H | Missense Mutation (SNP) | VAF 107/212 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV100184471; called by muse, mutect2, varscan2
- ZNF302 | c.572C>T p.S191F (on ENST00000627982; = p.S112F on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs761667917, COSV101416494; called by muse, mutect2, varscan2
- ZNF44 | c.1277C>T p.S426L (on ENST00000356109 / NM_001164276.2; = p.S378L on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/125 reads (87%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV100633568; called by muse, mutect2, varscan2
- ZNF536 | c.3292G>T p.G1098C | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.342); catalogued as COSV62827646, COSV62833574; called by muse, mutect2, varscan2
- ZNF592 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV100245869; called by muse, mutect2, varscan2
- ZNF705A | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as rs1236253753, COSV63732999; called by muse, mutect2, varscan2
- ZNF804A | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 63/108 reads (58%) | catalogued as COSV100167923; called by muse, mutect2, varscan2
- ZNFX1 | c.2992G>T p.V998L | Missense Mutation (SNP) | VAF 163/406 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.123); catalogued as COSV100870851; called by muse, mutect2, varscan2
- ZNFX1 | c.2991G>T p.K997N | Missense Mutation (SNP) | VAF 164/409 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as COSV100870853; called by muse, mutect2, varscan2
- ZSCAN1 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 67/88 reads (76%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.621); catalogued as COSV99991691; called by muse, mutect2, varscan2
- ZSCAN20 | c.1499A>T p.E500V | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792605; called by muse, mutect2, varscan2
- C1orf112 | c.1484_1486del p.I495del | In Frame Del (DEL) | VAF 32/146 reads (22%) | called by pindel, varscan2
- CD84 | c.162del p.W54* | Frame Shift Del (DEL) | VAF 31/135 reads (23%) | called by mutect2, pindel, varscan2
- CREB3L4 | c.785_798del p.K262Rfs*59 | Frame Shift Del (DEL) | VAF 24/53 reads (45%) | called by mutect2, pindel, varscan2
- DSCAM | c.2350del p.V784Lfs*6 | Frame Shift Del (DEL) | VAF 38/140 reads (27%) | called by mutect2, pindel, varscan2
- ERCC6L2 | c.4286dup p.L1430Afs*12 | Frame Shift Ins (INS) | VAF 32/46 reads (70%) | called by mutect2, varscan2
- ERCC6L2 | c.4287delinsTC p.L1430Pfs*12 | Frame Shift Ins (INS) | VAF 33/73 reads (45%) | called by mutect2*, pindel, varscan2*
- GOLGA6L9 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- HBD | c.383_387dup p.A130Rfs*? | Frame Shift Ins (INS) | VAF 20/120 reads (17%) | called by mutect2, pindel, varscan2
- HNRNPC | c.921del p.*307= (on ENST00000420743; = p.*294= on NM_004500.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 91/266 reads (34%) | called by mutect2, pindel, varscan2
- IGHV3-35 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 55/271 reads (20%) | called by muse, mutect2, varscan2
- MSMB | c.149C>A p.S50* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- NRM | c.187dup p.L63Pfs*21 | Frame Shift Ins (INS) | VAF 23/119 reads (19%) | called by mutect2, pindel, varscan2
- PIAS2 | c.463_473del p.D155Cfs*31 | Frame Shift Del (DEL) | VAF 23/54 reads (43%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.1162C>G p.P388A | Missense Mutation (SNP) | VAF 284/399 reads (71%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- RIMS1 | c.3630A>T p.K1210N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.154); called by muse, mutect2
- RSPH4A | c.1897_1915del p.Y633Kfs*8 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- SVIL | c.4038del p.E1347Sfs*19 (on ENST00000355867 / NM_021738.3; = p.E921Sfs*19 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- VSIG4 | c.493T>C p.C165R | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACTN2 | c.654C>T p.I218= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as rs1195889818, COSV100856806; called by muse, mutect2, varscan2
- ASIC5 | c.921T>C p.F307= | Silent (SNP) | VAF 35/53 reads (66%) | catalogued as COSV101611137; called by muse, mutect2, varscan2
- B3GAT3 | c.534G>A p.E178= | Silent (SNP) | VAF 103/186 reads (55%) | catalogued as COSV99605929; called by muse, mutect2, varscan2
- BRINP3 | c.2094A>T p.S698= | Silent (SNP) | VAF 66/108 reads (61%) | catalogued as COSV100818759; called by muse, mutect2, varscan2
- CD5L | c.106C>A p.R36= | Silent (SNP) | VAF 38/162 reads (23%) | catalogued as rs145458344, COSV63821515; called by muse, mutect2, varscan2
- CD81 | c.486G>C p.L162= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs577639930, COSV99719199; called by muse, mutect2, varscan2
- CDHR2 | c.2565G>T p.G855= | Silent (SNP) | VAF 47/65 reads (72%) | catalogued as COSV56142007, COSV99992304; called by muse, mutect2, varscan2
- DNAH10 | c.1098C>G p.V366= (on ENST00000409039; = p.V305= on NM_207437.3) | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as rs755846507, COSV101292254; called by muse, mutect2, varscan2
- DPYS | c.1368G>C p.T456= | Silent (SNP) | VAF 137/419 reads (33%) | catalogued as COSV60910110; called by muse, mutect2, varscan2
- ERCC3 | c.273A>T p.P91= | Silent (SNP) | VAF 54/93 reads (58%) | catalogued as COSV99573347; called by muse, mutect2, varscan2
- FBXL3 | c.294G>C p.L98= | Silent (SNP) | VAF 36/42 reads (86%) | catalogued as COSV100842358; called by muse, mutect2, varscan2
- FSTL3 | c.594G>T p.A198= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV51261402, COSV99383873; called by muse, mutect2, varscan2
- HBG1 | c.141C>A p.G47= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100400635; called by muse, varscan2
- HPGD | c.435T>A p.V145= | Silent (SNP) | VAF 27/37 reads (73%) | catalogued as COSV99640389; called by muse, mutect2, varscan2
- HS1BP3 | c.774A>G p.S258= | Silent (SNP) | VAF 51/95 reads (54%) | catalogued as COSV100397961; called by muse, mutect2, varscan2
- IMPG1 | c.228G>T p.T76= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as rs372049150, COSV100886392; called by muse, mutect2, varscan2
- IQSEC1 | c.555G>A p.E185= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV99831891; called by muse, mutect2, varscan2
- ITPR1 | c.2112C>T p.S704= (on ENST00000354582; = p.S689= on NM_002222.7) | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100231187; called by muse, mutect2, varscan2
- KASH5 | c.24G>A p.V8= | Silent (SNP) | VAF 26/33 reads (79%) | catalogued as COSV101483443, COSV101483528; called by muse, mutect2, varscan2
- KCND3 | c.270G>A p.V90= | Silent (SNP) | VAF 88/189 reads (47%) | catalogued as COSV100137365; called by muse, mutect2, varscan2
- KDM4C | c.2343G>T p.A781= | Silent (SNP) | VAF 29/45 reads (64%) | catalogued as COSV101184822, COSV67187119; called by muse, mutect2, varscan2
- KIAA1755 | c.1944C>T p.V648= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV99642030; called by muse, mutect2, varscan2
- KRT33B | c.78C>T p.C26= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV99290633; called by muse, varscan2
- KRTAP8-1 | c.67C>T p.L23= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV100297825; called by muse, mutect2, varscan2
- LIMK1 | c.540C>T p.V180= | Silent (SNP) | VAF 220/405 reads (54%) | catalogued as rs782378399, COSV60285937; called by muse, mutect2, varscan2
- LRRK1 | c.5163G>A p.L1721= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as rs1368457120, COSV99440086; called by muse, mutect2, varscan2
- MAGI3 | c.648A>C p.A216= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV100289011; called by muse, mutect2, varscan2
- MCM6 | c.246G>A p.E82= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as COSV99919063; called by muse, mutect2, varscan2
- MFHAS1 | c.3018C>G p.P1006= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs141053249; called by muse, mutect2, varscan2
- MOXD1 | c.228C>A p.V76= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV100914303; called by muse, mutect2, varscan2
- MX1 | c.522G>T p.L174= | Silent (SNP) | VAF 54/235 reads (23%) | catalogued as COSV99912633; called by muse, mutect2, varscan2
- MYO10 | c.6126G>A p.K2042= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1423356665, COSV99945362; called by muse, varscan2
- NIM1K | c.519C>T p.S173= | Silent (SNP) | VAF 28/226 reads (12%) | catalogued as COSV100390160; called by muse, mutect2, varscan2
- NR0B2 | c.63C>A p.L21= | Silent (SNP) | VAF 54/87 reads (62%) | catalogued as COSV99575009; called by muse, mutect2, varscan2
- NSD1 | c.7740G>A p.A2580= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs886485004, COSV61772634; called by muse, mutect2, varscan2
- NSD3 | c.3153G>A p.L1051= | Silent (SNP) | VAF 78/989 reads (8%) | catalogued as COSV100395328; called by muse, mutect2
- NUTM2D | c.162T>C p.N54= | Silent (SNP) | VAF 77/236 reads (33%) | catalogued as rs759229523, COSV101096944; called by muse, mutect2, varscan2
- OR14A16 | c.48T>C p.S16= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as rs1423922254, COSV100713784; called by muse, mutect2, varscan2
- OR2M4 | c.414G>T p.P138= | Silent (SNP) | VAF 65/133 reads (49%) | catalogued as COSV100141225, COSV60707635; called by muse, mutect2, varscan2
- OR4K5 | c.228T>C p.F76= | Silent (SNP) | VAF 69/367 reads (19%) | catalogued as COSV100262387; called by muse, mutect2, varscan2
- OR52B4 | c.465T>C p.Y155= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV101281590; called by muse, mutect2, varscan2
- OR5AC2 | c.495A>T p.L165= | Silent (SNP) | VAF 61/201 reads (30%) | catalogued as COSV100684389; called by muse, mutect2, varscan2
- OR6B1 | c.129G>A p.V43= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs766881943, COSV68770261; called by muse, mutect2, varscan2
- PCDHA1 | c.84C>T p.S28= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as rs1554117361, COSV65372805; called by muse, mutect2, varscan2
- PCDHB15 | c.462G>T p.L154= | Silent (SNP) | VAF 108/134 reads (81%) | catalogued as COSV99178921; called by muse, mutect2, varscan2
- PEAK1 | c.4272C>T p.D1424= | Silent (SNP) | VAF 46/134 reads (34%) | catalogued as rs770564562, COSV56940465; called by muse, mutect2, varscan2
- PPM1H | c.1446G>T p.L482= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as COSV99955845; called by muse, mutect2, varscan2
- PRB3 | c.861C>A p.P287= (on ENST00000381842; = p.P329= on NM_006249.5) | Silent (SNP) | VAF 157/283 reads (55%) | catalogued as rs754850693, COSV99685765; called by muse, mutect2, varscan2
- QRSL1 | c.741G>T p.L247= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100945225; called by muse, mutect2, varscan2
- RBM19 | c.2448C>G p.A816= | Silent (SNP) | VAF 57/78 reads (73%) | catalogued as rs777659324, COSV99926084; called by muse, mutect2, varscan2
- RP1L1 | c.133C>A p.R45= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as CM105618, COSV100261959; called by muse, mutect2, varscan2
- RYR1 | c.4074G>C p.G1358= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100615732; called by muse, varscan2
- SCTR | c.1322G>A p.*441= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99191585; called by muse, mutect2, varscan2
- SHANK2 | c.2037A>G p.L679= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99574040; called by muse, mutect2, varscan2
- SLC6A17 | c.549C>T p.V183= | Silent (SNP) | VAF 55/129 reads (43%) | catalogued as rs754215924, COSV100521294; called by muse, mutect2, varscan2
- SLCO1C1 | c.1323C>T p.S441= | Silent (SNP) | VAF 70/237 reads (30%) | catalogued as COSV56873643, COSV99859128; called by muse, mutect2, varscan2
- SLITRK3 | c.2262C>A p.P754= | Silent (SNP) | VAF 59/106 reads (56%) | catalogued as COSV53849687, COSV99578690; called by muse, mutect2, varscan2
- SOAT1 | c.282C>T p.L94= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV100858957; called by muse, mutect2, varscan2
- TLN2 | c.2902C>T p.L968= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV60893072; called by muse, mutect2, varscan2
- TMEM132D | c.2154C>A p.G718= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV101242836, COSV67162423; called by muse, mutect2, varscan2
- TTC7B | c.978A>G p.E326= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV100127944, COSV60640970; called by muse, mutect2, varscan2
- TTN | c.68166C>A p.A22722= (on ENST00000591111; = p.A15298= on NM_003319.4) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100612794; called by muse, mutect2, varscan2
- TTN | c.41100G>C p.V13700= (on ENST00000591111; = p.V6276= on NM_003319.4) | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as COSV100612798; called by muse, mutect2, varscan2
- TTN | c.24249G>A p.L8083= (on ENST00000591111; = p.L7156= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV100612801; called by muse, mutect2, varscan2
- TTN | c.18747C>A p.G6249= (on ENST00000591111; = p.G5322= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100612803; called by muse, mutect2, varscan2
- USF3 | c.405T>G p.S135= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as COSV100325259; called by muse, mutect2, varscan2
- USP1 | c.1746G>A p.V582= | Silent (SNP) | VAF 62/93 reads (67%) | catalogued as COSV99224427; called by muse, mutect2, varscan2
- XIRP2 | c.6642T>C p.S2214= (on ENST00000628543; = p.S2389= on NM_152381.6) | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as COSV99742935, COSV99743957; called by muse, mutect2, varscan2
- YES1 | c.1344G>T p.R448= | Silent (SNP) | VAF 49/338 reads (14%) | catalogued as COSV100099566, COSV100100027; called by muse, mutect2, varscan2
- ZEB2 | c.1158C>G p.G386= | Silent (SNP) | VAF 47/95 reads (49%) | catalogued as COSV100356017; called by muse, mutect2, varscan2
- ZNF773 | c.786C>T p.L262= | Silent (SNP) | VAF 98/129 reads (76%) | catalogued as rs1367850931, COSV56588210, COSV99989287; called by muse, mutect2, varscan2
- ANKRD13D | c.*782del | 3'UTR (DEL) | VAF 35/156 reads (22%) | called by mutect2, pindel, varscan2
- DEPDC5 | c.1870+2311G>C | Intron (SNP) | VAF 61/176 reads (35%) | catalogued as COSV99835375; called by muse, mutect2, varscan2
- MIR29B1 | n.65A>G | RNA (SNP) | VAF 99/163 reads (61%) | called by muse, mutect2, varscan2
- TPM3 | chr1:154159043 G>A | 3'Flank (SNP) | VAF 18/68 reads (26%) | catalogued as rs1219020570, COSV99666408; called by muse, mutect2, varscan2
- TTN | c.10360+1129C>A | Intron (SNP) | VAF 95/216 reads (44%) | catalogued as COSV60149865, COSV60172811; called by muse, mutect2, varscan2
